Somatic mutation profile of tumor specimen TCGA-DJ-A3VK-01A (aliquot TCGA-DJ-A3VK-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3VK, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 63.7 years (23,255 days).
Specimen TCGA-DJ-A3VK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1176a608-bbe1-4c78-851d-6f990d2103c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3VK-10A (Blood Derived Normal), aliquot TCGA-DJ-A3VK-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16d41892-415e-445f-b428-d6defff30742

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARCN1 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99873552; called by muse, mutect2, varscan2
- KCND3 | c.523A>G p.N175D | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV100137074; called by muse, mutect2
- OR51E2 | c.175T>C p.Y59H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101211329; called by muse, mutect2
- RAI14 | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as rs770006058, COSV99462504; called by muse, mutect2, varscan2
- SNX20 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV56057321; called by muse, mutect2
- TAF1L | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99644395; called by muse, mutect2, varscan2
- UNC79 | c.7423G>A p.A2475T (on ENST00000393151 / NM_001346218.2; = p.A2298T on NM_020818.5) | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs369445399; called by muse, mutect2
- VMP1 | c.1008G>C p.K336N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as COSV99230134; called by muse, mutect2, varscan2
- XYLT2 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99190823; called by muse, mutect2, varscan2
- ZCCHC10 | c.136C>G p.Q46E (on ENST00000509437 / NM_001300818.3; = p.Q24E on NM_017665.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100147887; called by muse, mutect2, varscan2
- ZNF438 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100061566; called by muse, mutect2
- MRPS18C | c.6C>T p.A2= | Silent (SNP) | VAF 47/232 reads (20%) | catalogued as rs760876096, COSV55026633; called by muse, mutect2, varscan2
- RNF215 | c.855C>T p.L285= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs764844213, COSV99306432; called by muse, mutect2, varscan2
